Somatic mutation profile of tumor specimen TARGET-10-PAPSPG-04A (aliquot TARGET-10-PAPSPG-04A-01D) from TARGET case TARGET-10-PAPSPG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.1 years (4,782 days).
Specimen TARGET-10-PAPSPG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5532ca5f-03ad-4070-8e6f-a3d6de8e4e54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPSPG-10A (Blood Derived Normal), aliquot TARGET-10-PAPSPG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b831ad2e-bb0d-4899-9a9a-d0ba8aa5e361

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 79/342 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP35 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68335337; called by muse, mutect2
- CDK11A | c.473A>C p.Q158P (on ENST00000378633 / NM_001313896.2; = p.Q168P on NM_024011.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.841); catalogued as rs1405746010; called by mutect2, varscan2
- CPXCR1 | c.828del p.C278Vfs*14 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as COSV52164376, COSV52164774; called by mutect2, pindel, varscan2
- ERCC8 | c.1061A>G p.K354R (on ENST00000265038; = p.K335R on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV54017976; called by muse, mutect2
- ETV1 | c.45+2T>C p.X15_splice | Splice Site (SNP) | VAF 64/239 reads (27%) | catalogued as COSV54150424; called by muse, mutect2, varscan2
- HEMK1 | c.615G>A p.R205= | Splice Region (SNP) | VAF 27/110 reads (25%) | catalogued as rs749445129, COSV51751872; called by muse, mutect2, varscan2
- ORM1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 69/707 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs745748857, COSV52278438; called by muse, mutect2, varscan2
- OTOGL | c.4661T>C p.L1554S (on ENST00000547103; = p.L1545S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022791; called by muse, mutect2
- PRKD1 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 67/242 reads (28%) | catalogued as rs1239799730, COSV59568048; called by muse, mutect2, varscan2
- PRPS1 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV65054659; called by muse, mutect2, varscan2
- RPGR | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV58839605; called by muse, mutect2
- RSPO3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259278709, COSV63152885; called by muse, mutect2
- TTC30A | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV63100532; called by muse, mutect2, varscan2
- VIT | c.1060C>T p.R354* (on ENST00000389975 / NM_001177969.1; = p.R369* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/185 reads (21%) | catalogued as rs377073906, COSV64895453, COSV64896966; called by muse, mutect2, varscan2
- TMEM236 | c.1044G>T p.M348I | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ADGB | c.60G>T p.S20= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV58863801; called by muse, mutect2, varscan2
- ADGRB3 | c.633G>A p.S211= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs144107434; called by muse, mutect2, varscan2
- ARFGEF3 | c.5802C>T p.G1934= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1317856418, COSV52451277; called by muse, mutect2, varscan2
- DSC2 | c.2592G>A p.S864= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1241309506, COSV51868670; called by muse, mutect2
- MUC16 | c.2493G>A p.S831= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as rs764383339, COSV67454733; called by muse, mutect2, varscan2
- PARP15 | c.498T>C p.H166= | Silent (SNP) | VAF 45/177 reads (25%) | catalogued as COSV59971537; called by muse, mutect2, varscan2
- PCYT2 | c.1074G>A p.A358= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs200834115; called by muse, mutect2, varscan2
- PSMB5 | c.506-1383G>A | Intron (SNP) | VAF 22/372 reads (6%) | catalogued as COSV57801211; called by muse, mutect2
